Somatic mutation profile of cancer-model specimen HCM-CSHL-0255-C18-85F (3D Organoid, passage 10; aliquot HCM-CSHL-0255-C18-85F-01D-A881-36), derived from the primary tumor of HCMI case HCM-CSHL-0255-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0255-C18-85F: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ce32b5b-0dc2-4264-9012-2c09f67ff088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0255-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0255-C18-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c683a2a-8cb0-4093-9b19-61ad6e8cff8b

The open-access MAF lists 83 somatic variants for this specimen: 59 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 23, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 245/245 reads (100%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/362 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 488/489 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 333/683 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs374032478; called by muse, mutect2, varscan2
- APOB | c.7600C>T p.R2534* | Nonsense Mutation (SNP) | VAF 535/812 reads (66%) | catalogued as rs145143533, CM051005; ClinVar: benign; called by muse, mutect2
- CASR | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 564/566 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs377282860, COSV56140790; called by muse, mutect2, varscan2
- CMBL | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 229/558 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs868855509; called by muse, mutect2, varscan2
- COL18A1 | c.2827G>A p.E943K (on ENST00000359759 / NM_130444.3; = p.E708K on NM_030582.4) | Missense Mutation (SNP) | VAF 299/619 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1271658589; called by muse, mutect2, varscan2
- COL27A1 | c.3892C>T p.R1298C | Missense Mutation (SNP) | VAF 207/472 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774923301, COSV61929888; called by muse, mutect2, varscan2
- CYP2D7 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 461/910 reads (51%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.529); catalogued as rs746357842; called by muse, mutect2, varscan2
- DNM1 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 274/588 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1372243765, COSV57848970; called by muse, mutect2, varscan2
- FAM98A | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 560/855 reads (65%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs764994064, COSV53210400; called by muse, mutect2, varscan2
- FANCG | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 204/448 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV62721400; called by muse, mutect2
- FAT3 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 144/297 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199786266; called by muse, mutect2, varscan2
- G6PC | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 217/462 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1444458077; called by muse, mutect2, varscan2
- GPNMB | c.1651G>A p.V551M (on ENST00000381990 / NM_001005340.2; = p.V539M on NM_002510.3) | Missense Mutation (SNP) | VAF 215/462 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs763870261, COSV51697415; called by muse, mutect2, varscan2
- HYOU1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 159/336 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.742); catalogued as rs373116532; called by muse, mutect2, varscan2
- IFITM5 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 440/876 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs747878124, COSV101164327; called by muse, mutect2, varscan2
- KNL1 | c.2680G>A p.D894N (on ENST00000346991 / NM_170589.5; = p.D868N on NM_144508.5) | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs765489557, COSV61161312; called by muse, mutect2, varscan2
- KRTAP5-10 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 256/610 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as rs746670846; called by mutect2, varscan2
- LMO7 | c.4083G>T p.E1361D (on ENST00000357063; = p.E1042D on NM_005358.5) | Missense Mutation (SNP) | VAF 210/553 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100413536; called by muse, mutect2, varscan2
- MTMR1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.798); catalogued as rs1557415635; called by muse, varscan2
- NAALADL1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 235/565 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751516383; called by muse, mutect2, varscan2
- PCDH8 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 439/1607 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs201490995; called by muse, varscan2
- PXDN | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 151/519 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs772534828, COSV53235772; called by muse, mutect2, varscan2
- RAMP3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 283/557 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370868982; called by muse, mutect2, varscan2
- REV3L | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs1328943223; called by muse, mutect2
- SARS1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 222/443 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750961565, COSV52320927; called by muse, mutect2, varscan2
- SCN5A | c.5663C>T p.S1888F (on ENST00000333535 / NM_198056.3; = p.S1887F on NM_000335.5) | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61120620; called by muse, mutect2, varscan2
- SH3TC1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 345/744 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs761407664; called by muse, mutect2, varscan2
- SORCS3 | c.3593C>T p.T1198M | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs139206461; called by muse, mutect2, varscan2
- TRIM44 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 260/531 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs771838525; called by muse, varscan2
- TRIM67 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 186/373 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs759061291, COSV64157994; called by muse, mutect2, varscan2
- TRPC3 | c.1944G>T p.K648N (on ENST00000379645 / NM_001366479.2; = p.K575N on NM_003305.2) | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV53377253; called by muse, mutect2, varscan2
- TSC2 | c.136_138+1del | Frame Shift Del (DEL) | VAF 172/179 reads (96%) | catalogued as rs137854117; called by mutect2, pindel, varscan2
- TTN | c.23164G>A p.V7722I (on ENST00000591111; = p.V6795I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 296/637 reads (46%) | PolyPhen benign (0.003); catalogued as rs759655046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VNN1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 214/476 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs774199628, COSV104425749; called by muse, mutect2, varscan2
- ARHGDIB | c.405A>T p.K135N | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DNAH7 | c.5363G>A p.R1788K | Missense Mutation (SNP) | VAF 157/338 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ENGASE | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 340/659 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- EZH2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 122/263 reads (46%) | called by muse, mutect2, varscan2
- GGTLC2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 100/421 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GNA15 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GPC5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 95/338 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KIF4B | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 629/636 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARK2 | c.2029G>A p.G677S (on ENST00000402010 / NM_001039469.2; = p.G613S on NM_004954.5) | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIOX | c.399_400insA p.E134Rfs*33 | Frame Shift Ins (INS) | VAF 221/603 reads (37%) | called by mutect2, pindel, varscan2
- MYOM2 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDE8A | c.244_249del p.V82_L83del | In Frame Del (DEL) | VAF 153/326 reads (47%) | called by mutect2, pindel, varscan2
- PLEKHG5 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 285/526 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- SHANK1 | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 236/550 reads (43%) | called by muse, mutect2, varscan2
- SMARCA5 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SNTG1 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 324/509 reads (64%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX4 | c.1242dup p.E415* | Frame Shift Ins (INS) | VAF 308/757 reads (41%) | called by mutect2, pindel, varscan2
- SYCP2L | c.2383C>G p.L795V | Missense Mutation (SNP) | VAF 189/383 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL2 | c.250del p.I84Sfs*63 | Frame Shift Del (DEL) | VAF 365/928 reads (39%) | called by mutect2, pindel, varscan2
- WASHC1 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 74/81 reads (91%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- XPO6 | c.3045+1G>A p.X1015_splice | Splice Site (SNP) | VAF 121/513 reads (24%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.1018_1043del p.A340Pfs*125 | Frame Shift Del (DEL) | VAF 506/1037 reads (49%) | called by mutect2, varscan2
- ACKR3 | c.489C>T p.V163= | Silent (SNP) | VAF 331/622 reads (53%) | catalogued as rs757673393, COSV56023815; called by muse, mutect2, varscan2
- ANKFN1 | c.1545C>T p.L515= | Silent (SNP) | VAF 184/355 reads (52%) | catalogued as rs770244166; called by muse, mutect2, varscan2
- BRWD3 | c.2559A>G p.S853= | Silent (SNP) | VAF 147/299 reads (49%) | called by muse, mutect2, varscan2
- CHIA | c.168C>T p.Y56= | Silent (SNP) | VAF 272/590 reads (46%) | catalogued as rs370883122; called by muse, mutect2
- COL6A3 | c.3750C>T p.Y1250= | Silent (SNP) | VAF 286/598 reads (48%) | catalogued as rs763648429, COSV55102627; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOK3 | c.96G>A p.L32= | Silent (SNP) | VAF 616/620 reads (99%) | called by muse, mutect2, varscan2
- ELOA3C | c.840C>T p.D280= | Silent (SNP) | VAF 52/459 reads (11%) | called by mutect2, varscan2
- GGN | c.1218C>T p.P406= | Silent (SNP) | VAF 327/672 reads (49%) | called by muse, mutect2, varscan2
- GLRA3 | c.321G>A p.A107= | Silent (SNP) | VAF 185/185 reads (100%) | catalogued as rs201476578, COSV56866241; called by muse, mutect2, varscan2
- HBD | c.141G>A p.G47= | Silent (SNP) | VAF 213/444 reads (48%) | catalogued as COSV99496617; called by muse, mutect2, varscan2
- HRNR | c.2133T>C p.S711= | Silent (SNP) | VAF 262/477 reads (55%) | called by muse, mutect2, varscan2
- IL9R | c.771C>T p.P257= | Silent (SNP) | VAF 225/506 reads (44%) | called by muse, mutect2, varscan2
- KCNA10 | c.1065G>A p.S355= | Silent (SNP) | VAF 278/520 reads (53%) | catalogued as rs566195238, COSV63904206; called by muse, mutect2, varscan2
- KIAA2012 | c.1317C>T p.H439= | Silent (SNP) | VAF 161/340 reads (47%) | catalogued as rs745369893, COSV99862421; called by muse, mutect2, varscan2
- KRT82 | c.675G>A p.L225= | Silent (SNP) | VAF 187/394 reads (47%) | catalogued as rs758654552, COSV99233356; called by muse, mutect2, varscan2
- LRIF1 | c.1485C>A p.V495= | Silent (SNP) | VAF 171/323 reads (53%) | called by muse, mutect2, varscan2
- MEGF6 | c.3426C>T p.H1142= | Silent (SNP) | VAF 347/716 reads (48%) | catalogued as rs375100441; called by muse, mutect2, varscan2
- PCDH19 | c.300C>T p.I100= | Silent (SNP) | VAF 402/839 reads (48%) | called by muse, mutect2, varscan2
- PSMC4 | c.609C>T p.L203= | Silent (SNP) | VAF 250/554 reads (45%) | catalogued as rs1448827771; called by muse, mutect2, varscan2
- SLC1A5 | c.279C>A p.G93= | Silent (SNP) | VAF 480/930 reads (52%) | called by muse, mutect2, varscan2
- TMEM119 | c.204G>C p.G68= | Silent (SNP) | VAF 327/705 reads (46%) | called by muse, mutect2, varscan2
- TPRX1 | c.198G>A p.A66= | Silent (SNP) | VAF 342/672 reads (51%) | catalogued as rs537091280; called by muse, varscan2
- TTN | c.29268C>T p.I9756= (on ENST00000591111; = p.I8829= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/300 reads (47%) | catalogued as rs369709449, COSV59976609; called by muse, mutect2, varscan2
- IGFN1 | c.1241+3686G>T | Intron (SNP) | VAF 270/604 reads (45%) | called by mutect2, varscan2
